CPTAC case C3L-01313 — Kidney — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e80deff0-6d18-4093-8d6d-ee481e4d06ac

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1953; Vital status: Dead; Days to death: 1,229 days (3.4 years); Year of death: 2020; Cause of death: Cancer Related; Country of birth: United States.

Diagnoses (1)
1. Renal cell carcinoma, NOS: ICD-O-3 morphology code: 8312/3; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Age at diagnosis: 63.7 years (23,275 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: MX; AJCC pathologic T: T3a; AJCC pathologic N: NX; AJCC pathologic M: MX; AJCC pathologic stage: Stage III; Tumor grade: G4; Residual disease: R0; Last known disease status: With tumor; Days to last known disease status: 1,229 days (3.4 years); Progression or recurrence: yes; Days to last follow up: 1,229 days (3.4 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 9 cm (a second GDC size field records 12 cm); Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 0; Margin status: Uninvolved; Sarcomatoid present: No.

Follow-up (4 entries)
- Days to follow up: 323 days; Disease response: Tumor Free.
- Days to follow up: 674 days (1.8 years); Disease response: With Tumor.
- Days to follow up: 1,016 days (2.8 years); Disease response: With Tumor.
- Days to follow up: 1,229 days (3.4 years); Disease response: With Tumor; Progression or recurrence: Yes; Days to recurrence: 456 days (1.2 years).

Other clinical attributes
- Weight: 80 kg; Height: 165 cm; BMI: 29.38.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 19; Cigarettes per day: 20; Tobacco smoking onset year: 1978; Tobacco smoking quit year: 1997; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker; Exposure duration years: 19.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-01313-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -5 days; Initial weight: 370 mg; Time between excision and freezing: 21 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-01313-23: Section location: Mid to inferior aspect; Percent tumor nuclei: 85; Percent necrosis: 5.
- Sample C3L-01313-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -5 days; Initial weight: 390 mg; Time between excision and freezing: 21 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-01313-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -5 days; Method of sample procurement: Blood Draw.
